Somatic mutation profile of tumor specimen HCM-BROD-0198-C71-01A (aliquot HCM-BROD-0198-C71-01A-11D-A78T-36) from HCMI case HCM-BROD-0198-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.8 years (21,484 days).
Specimen HCM-BROD-0198-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52191b41-af75-45a6-bbd0-545d6807e355.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0198-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0198-C71-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/75a3ee1b-aa06-44be-878b-72db1a65e434

The open-access MAF lists 57 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Intron 5, Frame Shift Del 2, 5'UTR 1, Translation Start Site 1, Nonsense Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen benign (0.264); catalogued as rs121913286, COSV55873527, COSV55882350; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 129/197 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs121909239, CM051216, CM159947, COSV64289881, COSV64296805, COSV64297163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2198G>A p.R733Q (on ENST00000372530 / NM_001198934.2; = p.R705Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150052458; called by muse, mutect2, varscan2
- ATP8B4 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 114/363 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs745355532, COSV52708582; called by muse, mutect2, varscan2
- COL11A1 | c.3044G>T p.G1015V | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1343845258, COSV100615753, COSV62178438; called by muse, mutect2, varscan2
- ESS2 | c.998C>T p.T333M | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs533003983, COSV52817462; called by muse, mutect2, varscan2
- FAT2 | c.2974C>T p.R992* | Nonsense Mutation (SNP) | VAF 126/390 reads (32%) | catalogued as COSV55828350; called by muse, mutect2, varscan2
- IGHV3-66 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 121/304 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.557); catalogued as rs781857160; called by muse, mutect2, varscan2
- IL2RA | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56919782; called by muse, mutect2, varscan2
- KCP | c.4015C>T p.R1339C (on ENST00000620378; = p.R1463C on NM_001366122.1) | Missense Mutation (SNP) | VAF 123/365 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs748855812; called by muse, mutect2, varscan2
- KRTAP1-3 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 166/510 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs775007516; called by muse, mutect2, varscan2
- LAMA5 | c.1499G>A p.G500E | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV53360309; called by muse, mutect2, varscan2
- LPA | c.5794G>A p.V1932I | Missense Mutation (SNP) | VAF 144/423 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.083); catalogued as rs761853859; called by muse, mutect2, varscan2
- NKD2 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 84/280 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as rs754988202; called by muse, mutect2, varscan2
- OR4S1 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs371001252, COSV100180378; called by muse, mutect2, varscan2
- PRODH2 | c.887G>A p.R296H (on ENST00000301175; = p.R220H on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374055330; called by muse, varscan2
- RBPJL | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1316863024, COSV100643470; called by muse, mutect2, varscan2
- SLC35G3 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 317/818 reads (39%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs765407465, COSV52012930; called by muse, mutect2, varscan2
- SOBP | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 154/389 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100433222; called by muse, mutect2, varscan2
- TICAM1 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs373468408, COSV99941051; called by muse, mutect2, varscan2
- ZIC2 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 280/772 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV66255530; called by muse, varscan2
- ZNF500 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 103/230 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1449140005; called by muse, mutect2, varscan2
- BBS9 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 57/237 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCS1L | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 53/166 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCDC168 | c.19619A>G p.N6540S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DGCR8 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 104/272 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOCAD | c.4301_4314del p.T1434Ifs*41 | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- JAG1 | c.1372T>C p.C458R | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCTD5 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL35 | c.691C>G p.R231G | Missense Mutation (SNP) | VAF 24/363 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB6C | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STAB2 | c.5155A>G p.I1719V | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STT3B | c.490_491del p.V164Sfs*14 | Frame Shift Del (DEL) | VAF 66/213 reads (31%) | called by mutect2, pindel, varscan2
- ZNF142 | c.2959C>T p.P987S (on ENST00000411696 / NM_001379660.1; = p.P787S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF814 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ZSCAN1 | c.916C>A p.H306N | Missense Mutation (SNP) | VAF 180/465 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ACSL6 | c.1473C>A p.L491= (on ENST00000379240; = p.L516= on NM_015256.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/142 reads (35%) | catalogued as COSV57297186, COSV57299406; called by muse, mutect2, varscan2
- BEST3 | c.1386G>A p.L462= | Silent (SNP) | VAF 107/260 reads (41%) | called by muse, mutect2, varscan2
- FSTL4 | c.291C>T p.Y97= | Silent (SNP) | VAF 168/440 reads (38%) | catalogued as rs762313986, COSV54772363; called by muse, mutect2, varscan2
- H1-6 | c.288C>T p.I96= | Silent (SNP) | VAF 168/466 reads (36%) | catalogued as rs776785708; called by muse, mutect2, varscan2
- MS4A8 | c.312C>T p.Y104= | Silent (SNP) | VAF 38/131 reads (29%) | catalogued as rs144254483, COSV55753762; called by muse, mutect2, varscan2
- NIBAN2 | c.696C>T p.N232= | Silent (SNP) | VAF 42/438 reads (10%) | catalogued as rs200335071, COSV64825714; called by muse, mutect2
- PCDHA5 | c.1350C>T p.N450= | Silent (SNP) | VAF 242/672 reads (36%) | catalogued as rs61730629, COSV65348992; called by muse, mutect2, varscan2
- PRLHR | c.657G>A p.E219= | Silent (SNP) | VAF 46/68 reads (68%) | called by muse, mutect2, varscan2
- TACR3 | c.750C>T p.I250= | Silent (SNP) | VAF 59/170 reads (35%) | catalogued as rs1006068692, COSV100510643; called by muse, mutect2, varscan2
- TROAP | c.93T>A p.P31= | Silent (SNP) | VAF 96/302 reads (32%) | called by muse, mutect2, varscan2
- UMODL1 | c.1845C>T p.G615= | Silent (SNP) | VAF 115/322 reads (36%) | catalogued as rs1388927822; called by muse, mutect2, varscan2
- USP43 | c.852G>A p.L284= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as rs1312679516; called by muse, mutect2, varscan2
- VRK1 | c.690C>T p.I230= | Silent (SNP) | VAF 119/342 reads (35%) | catalogued as rs747694940; ClinVar: likely benign; called by muse, mutect2
- FCRL6 | c.-20G>A | 5'UTR (SNP) | VAF 61/143 reads (43%) | catalogued as rs371412089; called by muse, mutect2, varscan2
- GALNT13 | c.1396-760C>T | Intron (SNP) | VAF 19/56 reads (34%) | catalogued as rs1485205423; called by muse, mutect2, varscan2
- GOLGA8S | c.348+25G>A | Intron (SNP) | VAF 58/317 reads (18%) | catalogued as rs1330179118; called by muse, mutect2, varscan2
- LAMC2 | c.3070-26G>A | Intron (SNP) | VAF 131/357 reads (37%) | catalogued as rs746973333; called by muse, mutect2, varscan2
- OSTM1 | c.*42G>A | 3'UTR (SNP) | VAF 33/100 reads (33%) | called by muse, mutect2, varscan2
- SV2C | c.581-21241G>A | Intron (SNP) | VAF 90/329 reads (27%) | called by muse, mutect2, varscan2
- TBC1D3P1 | n.135C>T | RNA (SNP) | VAF 187/490 reads (38%) | catalogued as rs780992440; called by muse, mutect2, varscan2
- TEKT2 | c.283-15C>T | Intron (SNP) | VAF 117/345 reads (34%) | catalogued as rs766262806; called by muse, mutect2, varscan2
